Gene-level copy-number profile of tumor specimen 1105231 from CPTAC case C208854, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen 1105231: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 892f96fd-0116-41ea-a636-bb4b63bcd6c5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105214 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/cd14df62-1346-409e-a005-d2839732ceac

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 5,495; copy number 2: 50,370; copy number 3: 2,959; copy number 4: 11; copy number 7: 5; copy number 20: 41; copy number 23: 18.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,128,103, 14 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 64 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,892,792–15,118,043, 1 gene, copy number 20 (within-gene range 2–20): KAZN.
- chr1:14,692,129–15,976,132, 40 genes, copy number 20 (within-gene range 2–20): TBCAP2, AL031293.1, TMEM51-AS1, TMEM51, C1orf195, MFFP1, ZBTB2P1, FHAD1, FHAD1-AS1, AL031283.2, AL031283.1, EFHD2, CTRC, CELA2A, CELA2B, CASP9, DNAJC16, SCARNA21B, AL121992.3, AGMAT, AL121992.1, CHCHD2P6, RNU7-179P, CD24P1, DDI2, RSC1A1, AL121992.2, PLEKHM2, AL450998.2, SLC25A34, SLC25A34-AS1, TMEM82, FBLIM1, RPL12P14, UQCRHL, AL450998.1, FLJ37453, SPEN, AL034555.1, ZBTB17.
- chr7:54,185,071–55,344,958, 18 genes, copy number 23: AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1.
- chr16:52,198,012–52,280,638, 3 genes, copy number 7: AC007333.2, AC007333.1, CASC22.
- chr16:52,436,772–52,437,474, 1 gene, copy number 7: AC007490.1.
- chr16:55,007,982–55,008,306, 1 gene, copy number 7: MTND5P34.

Autosomal genes at a single copy (total copy number 1): 2,639. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
